Gene-level copy-number profile of tumor specimen TCGA-70-6722-01A from TCGA case TCGA-70-6722, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 47.4 years (17,328 days).
Specimen TCGA-70-6722-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.420e849d-6ba2-4a1e-a2be-ba7bf89e6f76.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-70-6722-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b72f0bd0-d632-4f50-b1d6-ae3449f79490

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 26; copy number 1: 5,950; copy number 2: 32,879; copy number 3: 16,538; copy number 4: 3,053; copy number 5: 438; copy number 6: 409; copy number 7: 227; copy number 8: 49; copy number 9: 56; copy number 11: 13; copy number 13: 24; copy number 15: 17; copy number 17: 62; copy number 19: 26; copy number 23: 45.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-70-6722-01A-11D-1816-01): tumor purity 0.32, ploidy 2.52, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 26 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:58,192,257–61,251,459, 26 genes (within-gene range 0–1): DNASE1L3, ABHD6, HTD2, RPP14, AC098479.1, PXK, AC135507.2, PDHB, AC135507.1, AC116036.2, KCTD6, ACOX2, AC116036.1, FAM107A, AC119424.1, FAM3D-AS1, FAM3D, CFAP20DC, CFAP20DC-AS1, AC126121.3, AC138057.1, AC126121.2, AC126121.1, Metazoa_SRP, FHIT, AC093418.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,366 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:126,557,435–127,811,187, 33 genes, copy number 6 (within-gene range 2–6): YWHAZP2, AC013474.2, GYPC, AC013474.1, RNU6-675P, TEX51, RNU7-182P, AC012508.2, AC012508.3, AC012508.1, BIN1, AC110926.1, NIFKP9, CYP27C1, WBP11P2, ERCC3, AC068282.1, MAP3K2, RNU6-1147P, MAP3K2-DT, AC068282.2, PROC, MIR4783, IWS1, AC010976.1, RNU4-48P, MYO7B, AC010976.2, LIMS2, GPR17, WDR33, SFT2D3, RNY4P7.
- chr2:196,189,099–196,593,684, 1 gene, copy number 5 (within-gene range 2–5): HECW2.
- chr2:196,638,422–198,772,356, 34 genes, copy number 5 (within-gene range 3–5): AC068544.2, CCDC150, AC068544.1, GTF3C3, C2orf66, AC012486.1, PGAP1, ANKRD44, HNRNPA3P15, RPL4P7, ANKRD44-AS1, ANKRD44-IT1, ATP5MC2P3, AC010746.2, NPM1P46, SF3B1, AC010746.1, RNU6-1029P, COQ10B, HSPD1, HSPE1, HSPE1-MOB4, MOB4, AC020550.1, RFTN2, AC020550.2, AC011997.1, MARS2, BOLL, PLCL1, AC011997.2, AC020719.1, LINC01923, AC019330.1.
- chr3:164,670,878–175,810,548, 145 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr5:58,198–13,944,543, 254 genes, copy number 5–13 (broad region; genes not listed).
- chr5:23,262,159–23,689,386, 7 genes, copy number 5: AC010460.2, Y_RNA, AC010460.3, AC010460.1, PRDM9, AC109445.1, AC108103.1.
- chr7:42,954,135–57,837,046, 336 genes, copy number 6–23 (within-gene range 4–23) (broad region; genes not listed).
- chr14:23,749,236–23,827,396, 4 genes, copy number 6: BRD7P1, AL160237.3, RN7SKP205, AL160237.2.
- chr14:27,258,717–30,191,898, 28 genes, copy number 8–15 (within-gene range 2–15): AL390334.1, LINC00645, MIR3171, BNIP3P1, AL139023.1, RPL26P3, LINC02300, EIF4A1P12, BTF3P2, FOXG1-AS1, AL049777.1, FOXG1, LINC01551, LINC02282, LINC02281, LINC02327, AL122126.1, LINC02326, Y_RNA, AL135878.1, RNU6-864P, AL133166.1, AL158058.1, AL158058.2, RNU11-5P, PRKD1, AL356756.1, RNU6-1234P.
- chr14:31,025,106–31,861,224, 19 genes, copy number 8 (within-gene range 2–8): AP4S1, HECTD1, RPL21P5, RNU6-541P, Y_RNA, AL136418.1, Y_RNA, HEATR5A, ATP5MC1P2, AL139353.1, AL139353.2, DTD2, AL163973.1, GPR33, NUBPL, AL163973.3, AL163973.2, RNU6-602P, RNU6-455P.
- chr14:32,934,396–43,596,683, 147 genes, copy number 5–11 (within-gene range 2–11) (broad region; genes not listed).
- chr14:61,811,974–69,214,092, 149 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr18:32,672,673–32,773,023, 1 gene, copy number 6 (within-gene range 2–6): KLHL14.
- chr20:22,587,522–23,928,954, 49 genes, copy number 5 (within-gene range 3–5): LNCNEF, LINC01747, AL158175.1, KRT18P3, CYB5AP4, AL353132.1, AL049651.1, AL049651.2, SSTR4, THBD, AL118508.3, CD93, LINC00656, AL118508.2, RNA5SP478, AL118508.1, AL390037.1, NXT1-AS1, NXT1, LINC01431, GZF1, NAPB, RNA5SP479, CSTL1, CST11, AL096677.1, Y_RNA, CST12P, AL109954.1, AL109954.2, CST8, CST13P, CST9LP1, CST9L, CST9LP2, CST9, CST3, AL121894.2, AL121894.1, AL121894.3, CST4, CST2P1, AL591074.2, CST1, CSTP2, AL591074.1, CST2, CST5, CSTP1.
- chr20:59,863,564–64,313,132, 159 genes, copy number 5–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,636. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
